Somatic mutation profile of tumor specimen C3L-00096-01 (aliquot CPT0001180005) from CPTAC case C3L-00096, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 52.5 years (19,180 days).
Specimen C3L-00096-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c770499-7f21-46a1-b914-88e60cdc270b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00096-31 (Blood Derived Normal), aliquot CPT0000050163; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00dbc272-120a-48bf-9a8c-fe8e8fc48104

The open-access MAF lists 64 somatic variants for this specimen: 43 protein-altering or splice-affecting, 11 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 11, Frame Shift Del 6, Intron 6, Frame Shift Ins 2, 3'UTR 2, Nonsense Mutation 2, Splice Site 2, 5'UTR 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.533T>C p.L178P | Missense Mutation (SNP) | VAF 141/419 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs5030822, CM003061, CM941386, CM961439, COSV56544319, COSV56547906, COSV56565675; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AP4B1 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 79/384 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs759341651; called by muse, mutect2, varscan2
- CFAP54 | c.4552C>T p.R1518* | Nonsense Mutation (SNP) | VAF 89/286 reads (31%) | catalogued as rs1043155735, COSV61571920; called by muse, mutect2, varscan2
- CYP2A7 | c.635C>T p.T212M | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.261); catalogued as rs138321167; called by muse, mutect2, varscan2
- DMXL1 | c.8585A>G p.N2862S | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.524); catalogued as rs201010087; called by muse, mutect2, varscan2
- DNAH17 | c.11204C>T p.T3735M | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs368944814; called by muse, varscan2
- FAT1 | c.10750C>T p.P3584S | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.099); catalogued as COSV71674231; called by muse, mutect2, varscan2
- HSPA8 | c.261G>A p.M87I | Missense Mutation (SNP) | VAF 32/374 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.012); catalogued as COSV57085946; called by muse, mutect2
- OLR1 | c.444G>C p.W148C | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58872721; called by muse, mutect2
- PDX1 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as rs1049166702, COSV66847150; called by muse, mutect2, varscan2
- PTGFR | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 53/192 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.816); catalogued as rs1259928177, COSV66115350; called by muse, mutect2, varscan2
- RIMBP2 | c.2452G>A p.V818M | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372504138; called by muse, varscan2
- SCAPER | c.2102G>A p.R701Q | Missense Mutation (SNP) | VAF 55/264 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV57738869; called by muse, mutect2, varscan2
- SFMBT2 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 31/301 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV62811652; called by muse, mutect2, varscan2
- TMTC2 | c.493T>A p.S165T | Missense Mutation (SNP) | VAF 93/207 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV58259008; called by muse, mutect2, varscan2
- AGBL2 | c.1844G>T p.R615L | Missense Mutation (SNP) | VAF 55/260 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ATAD2 | c.4018_4019del p.V1340Cfs*2 | Frame Shift Del (DEL) | VAF 20/224 reads (9%) | called by mutect2, pindel
- BRPF1 | c.2840G>C p.S947T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- CFAP20DC | c.587C>T p.T196I (on ENST00000482387 / NM_001351530.2; = p.T71I on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CRYBG1 | c.1923-8_1927delinsTTTCTTTTTTCTT p.X641_splice | Splice Site (ONP) | VAF 5/61 reads (8%) | called by mutect2*, pindel
- CUL9 | c.5863G>T p.E1955* | Nonsense Mutation (SNP) | VAF 63/173 reads (36%) | called by muse, mutect2, varscan2
- ENKD1 | c.779C>A p.A260D | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- FASTKD1 | c.857T>C p.I286T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- GNAI3 | c.1019_1020del p.T340Rfs*5 | Frame Shift Del (DEL) | VAF 33/148 reads (22%) | called by mutect2, pindel, varscan2
- GRIK4 | c.2515-2A>T p.X839_splice | Splice Site (SNP) | VAF 43/237 reads (18%) | called by muse, mutect2, varscan2
- KIF1B | c.3747G>C p.K1249N (on ENST00000377086 / NM_001365952.1; = p.K1203N on NM_015074.3) | Missense Mutation (SNP) | VAF 76/326 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.226); called by muse, varscan2
- KLC3 | c.471C>G p.D157E | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MSL1 | c.1800G>T p.L600F (on ENST00000398532 / NM_001365919.1; = p.L337F on NM_001012241.2) | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- MUC16 | c.17360C>A p.T5787N | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- MYBL1 | c.2005_2006insT p.D669Vfs*3 | Frame Shift Ins (INS) | VAF 22/196 reads (11%) | called by mutect2, pindel
- NELL2 | c.327G>C p.L109F | Missense Mutation (SNP) | VAF 53/299 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- PLCH2 | c.3696dup p.F1233Lfs*31 | Frame Shift Ins (INS) | VAF 89/374 reads (24%) | called by mutect2, pindel, varscan2
- PLXNA2 | c.2440T>C p.C814R | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PRDM15 | c.2592G>T p.G864= | Splice Region (SNP) | VAF 57/211 reads (27%) | called by muse, mutect2, varscan2
- RCN3 | c.957_958del p.D320Pfs*7 | Frame Shift Del (DEL) | VAF 43/222 reads (19%) | called by mutect2, pindel, varscan2
- RELN | c.6392del p.Q2131Rfs*31 | Frame Shift Del (DEL) | VAF 105/377 reads (28%) | called by mutect2, pindel, varscan2
- RELN | c.3769A>G p.M1257V | Missense Mutation (SNP) | VAF 120/345 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- RSF1 | c.1235del p.E412Gfs*3 | Frame Shift Del (DEL) | VAF 19/114 reads (17%) | called by mutect2, pindel, varscan2
- SLC29A2 | c.1134C>G p.C378W | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC39A1 | c.334C>A p.Q112K | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.597); called by mutect2, varscan2
- SMG7 | c.1273_1274del p.L425Gfs*43 | Frame Shift Del (DEL) | VAF 37/212 reads (17%) | called by mutect2, pindel, varscan2
- THUMPD1 | c.465G>T p.K155N | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- TP53AIP1 | c.139T>A p.W47R | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- C1QL4 | c.387C>T p.D129= | Silent (SNP) | VAF 63/317 reads (20%) | catalogued as rs1565675281; called by muse, mutect2, varscan2
- CKAP2 | c.1470A>T p.A490= (on ENST00000378037 / NM_001098525.2; = p.A489= on NM_018204.5) | Silent (SNP) | VAF 56/202 reads (28%) | called by muse, mutect2, varscan2
- FRMD4A | c.2229C>T p.P743= | Silent (SNP) | VAF 54/197 reads (27%) | catalogued as rs1564530865; called by muse, mutect2, varscan2
- MRGBP | c.102G>A p.E34= | Silent (SNP) | VAF 30/124 reads (24%) | catalogued as rs552458407; called by muse, mutect2, varscan2
- MYO16 | c.4218C>T p.D1406= | Silent (SNP) | VAF 24/182 reads (13%) | called by muse, mutect2, varscan2
- NALCN | c.5124C>T p.D1708= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as rs1468254746, COSV51975679; called by muse, mutect2, varscan2
- PCSK2 | c.1251C>T p.S417= | Silent (SNP) | VAF 29/119 reads (24%) | called by muse, mutect2, varscan2
- SBF2 | c.3526C>A p.R1176= | Silent (SNP) | VAF 30/363 reads (8%) | catalogued as COSV99814989; called by muse, mutect2
- UST | c.1147C>T p.L383= | Silent (SNP) | VAF 64/214 reads (30%) | catalogued as rs778113075; called by muse, mutect2, varscan2
- VWA5B2 | c.1761T>C p.F587= | Silent (SNP) | VAF 8/38 reads (21%) | called by muse, varscan2
- ZNF350 | c.618T>C p.H206= | Silent (SNP) | VAF 52/251 reads (21%) | called by muse, mutect2, varscan2
- CEP126 | c.507-2373C>T | Intron (SNP) | VAF 8/34 reads (24%) | called by muse, varscan2
- GOLT1B | c.117+158T>A | Intron (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2, varscan2
- HMGN2 | c.-60C>A | 5'UTR (SNP) | VAF 95/377 reads (25%) | called by muse, mutect2, varscan2
- MTMR2 | c.262+33C>T | Intron (SNP) | VAF 59/201 reads (29%) | called by muse, mutect2, varscan2
- OXR1 | c.224-61082T>C | Intron (SNP) | VAF 205/347 reads (59%) | catalogued as rs1315697079; called by muse, mutect2, varscan2
- PPARGC1B | c.78+2413T>C | Intron (SNP) | VAF 40/173 reads (23%) | called by muse, mutect2, varscan2
- S100A1 | chr1:153628409 del ACAGGTCTCCACAC | 5'Flank (DEL) | VAF 26/106 reads (25%) | called by mutect2, pindel
- SLC2A1 | c.*349A>T | 3'UTR (SNP) | VAF 24/92 reads (26%) | called by muse, mutect2, varscan2
- SLC2A1 | c.*348G>T | 3'UTR (SNP) | VAF 23/93 reads (25%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+955C>G | Intron (SNP) | VAF 38/136 reads (28%) | catalogued as rs1369447294; called by muse, mutect2, varscan2
